TCGA case TCGA-LB-A9Q5 — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Candler. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/31c23e65-1f18-4f59-8a54-31febedef8a2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 63 years; Vital status: Dead; Days to death: 313 days; Cause of death: Cancer Related.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 63.6 years (23,218 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 313 days; Sites of involvement: Pancreas Head; Tumor grade category: Three Tier.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 12; Tumor largest dimension diameter: 3 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Days to treatment start: 64 days; Days to treatment end: 169 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 198 days; Days to treatment end: 238 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 198 days; Days to treatment end: 238 days; Treatment dose: 50 Gy; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Nab-paclitaxel; Days to treatment start: 303 days; Days to treatment end: 310 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Days to treatment start: 310 days; Days to treatment end: 310 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Whipple.
2. Recurrence of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Specified parts of peritoneum. Age at diagnosis: 64.4 years (23,508 days); Days to diagnosis: 290 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 290 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Specified parts of peritoneum; Days to recurrence: 290 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 313 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 155.

Exposures
- Alcohol history: No; Alcohol intensity: Non-Drinker.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 0.3; Tobacco smoking onset year: 1971; Tobacco smoking quit year: 1973.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-LB-A9Q5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 170 mg.
  Slide TCGA-LB-A9Q5-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 70; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 10.
- Sample TCGA-LB-A9Q5-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-LB-A9Q5-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymph nodes examined: Yes; Tobacco smoking history indicator: 3; Alcohol history documented: Yes; Diabetes diagnosis indicator: No; History chronic pancreatitis: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Cause of death: Pancreatic Cancer.
- Drug treatment 1: Pharmaceutical therapy drug name: Gemcitabine HCL.
- Drug treatment 2: Pharmaceutical therapy drug name: 5 FU.
- Drug treatment 3: Pharmaceutical therapy drug name: gemcitabine HCL; Treatment best response: Clinical Progressive Disease.
- Drug treatment 4: Pharmaceutical therapy drug name: Abraxane; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 313 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 313 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 290 days.
